Gene-level copy-number profile of tumor specimen TCGA-C9-A47Z-01A from TCGA case TCGA-C9-A47Z, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 72.8 years (26,592 days).
Specimen TCGA-C9-A47Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.30cd4730-b263-471b-835d-c1d4c961ba6f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C9-A47Z-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4ffbd268-c64a-42b2-88ef-d8e8d21b5076

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 2,343; copy number 3: 25,698; copy number 4: 28,061; copy number 5: 1,034; copy number 6: 1,599; copy number 7: 493; copy number 8: 345; copy number 9: 58; copy number 10: 22; copy number 12: 15; copy number 14: 7; copy number 20: 50; copy number 23: 16; copy number 27: 17; copy number 30: 52; copy number 32: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C9-A47Z-01A-11D-A24C-01): tumor purity 0.66, ploidy 3.57, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,079 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:52,165,235–56,448,375, 87 genes, copy number 8–12 (within-gene range 4–12) (broad region; genes not listed).
- chr9:4,741,741–14,722,733, 127 genes, copy number 14–32 (broad region; genes not listed).
- chr9:14,779,930–14,791,158, 2 genes, copy number 32: AL512643.2, AL512643.1.
- chr11:65,823,022–85,627,922, 551 genes, copy number 7–9 (within-gene range 3–9) (broad region; genes not listed).
- chr18:2,916,994–3,013,144, 1 gene, copy number 27 (within-gene range 2–27): LPIN2.
- chr18:2,948,238–15,330,282, 311 genes, copy number 8–27 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
